Somatic mutation profile of tumor specimen C3L-02354-02 (aliquot CPT0112910009) from CPTAC case C3L-02354, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G1; Age at diagnosis: 55.5 years (20,260 days).
Specimen C3L-02354-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18160bab-6937-492e-9869-3de1e20b25af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02354-31 (Blood Derived Normal), aliquot CPT0115210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0058a7f0-5932-49c8-965f-8ae3b6f2fd33

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 14, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 132/148 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 112/294 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 168/408 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.933G>A p.T311= | Splice Region (SNP) | VAF 38/88 reads (43%) | catalogued as COSV52217053; called by muse, mutect2, varscan2
- CHP2 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 30/474 reads (6%) | catalogued as rs267604473; called by muse, mutect2
- GRIP1 | c.2032C>T p.R678C (on ENST00000359742 / NM_001379345.1; = p.R626C on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 146/327 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs991022034; called by muse, varscan2
- HCRTR1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757082425, COSV65485370; called by muse, mutect2, varscan2
- HECW2 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.993); catalogued as rs1332568073; called by muse, mutect2, varscan2
- HMCN2 | c.14456G>A p.R4819Q | Missense Mutation (SNP) | VAF 160/443 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.103); catalogued as rs777016704, COSV100203558; called by muse, mutect2, varscan2
- LOXHD1 | c.5713G>A p.V1905M (on ENST00000642948; = p.V1843M on NM_144612.7) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406257799, COSV100192113; called by muse, mutect2, varscan2
- LSP1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs145216198; called by muse, mutect2, varscan2
- MMRN2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs376575577; called by muse, mutect2, varscan2
- MOGS | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs756186613; called by muse, mutect2, varscan2
- MTOR | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63868896; called by muse, mutect2
- MTOR | c.4171C>G p.R1391G | Missense Mutation (SNP) | VAF 130/372 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100815589, COSV63874955; called by muse, mutect2, varscan2
- MYH8 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 38/609 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563940083, COSV101238451; called by muse, mutect2
- OR1A2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs775857630, COSV67936143; called by muse, mutect2, varscan2
- OR51Q1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs866002052, COSV56179996; called by muse, mutect2, varscan2
- PCLO | c.14914C>G p.L4972V | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV61644631; called by muse, mutect2, varscan2
- PDLIM4 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1454884302; called by muse, varscan2
- SHROOM4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs376604578, COSV56788702; ClinVar: uncertain significance; called by muse, mutect2
- SORCS3 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63818370; called by muse, mutect2
- TFAP2D | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 131/377 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs373333958; called by muse, mutect2, varscan2
- USP9X | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 82/241 reads (34%) | catalogued as COSV61067883; called by muse, mutect2, varscan2
- WDR7 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs754502297, COSV54353613; called by muse, mutect2, varscan2
- C8B | c.464G>C p.C155S | Missense Mutation (SNP) | VAF 205/551 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CEL | c.658G>T p.G220C (on ENST00000673714; = p.G217C on NM_001807.6) | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- HNRNPD | c.433_436del p.F145Kfs*6 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by mutect2, pindel, varscan2
- INSL6 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LVRN | c.918C>G p.Y306* | Nonsense Mutation (SNP) | VAF 108/291 reads (37%) | called by muse, mutect2, varscan2
- MAP7D3 | c.2138_2139del p.R714Nfs*25 | Frame Shift Del (DEL) | VAF 36/115 reads (31%) | called by mutect2, pindel, varscan2
- METTL3 | c.1205T>G p.M402R | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SI | c.3279T>A p.F1093L | Missense Mutation (SNP) | VAF 153/452 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TBC1D8 | c.2312T>G p.F771C | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNKS2 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- TTLL11 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 126/396 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- COL5A1 | c.888C>T p.P296= | Silent (SNP) | VAF 149/337 reads (44%) | catalogued as rs747624704; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAP | c.780C>G p.P260= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as COSV99502621; called by muse, mutect2, varscan2
- GUCY2D | c.180C>T p.G60= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as rs753766842, COSV99644263; called by muse, mutect2, varscan2
- HOXA11 | c.114G>A p.P38= | Silent (SNP) | VAF 15/344 reads (4%) | called by muse, mutect2
- ITGA2 | c.1902C>T p.T634= | Silent (SNP) | VAF 121/435 reads (28%) | catalogued as rs144430073; called by muse, mutect2, varscan2
- MYOM2 | c.90C>T p.D30= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs1204656774; called by muse, mutect2
- PRR19 | c.750G>A p.A250= | Silent (SNP) | VAF 113/271 reads (42%) | catalogued as rs980761495, COSV100003986; called by muse, mutect2, varscan2
- SIRT2 | c.180C>T p.D60= | Silent (SNP) | VAF 66/264 reads (25%) | catalogued as rs201677615; called by muse, mutect2, varscan2
- SNX18 | c.330A>G p.P110= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs771136464; called by muse, mutect2, varscan2
- SOX18 | c.1098C>T p.I366= | Silent (SNP) | VAF 92/231 reads (40%) | catalogued as rs376704068, COSV61110529; called by muse, mutect2, varscan2
- TLL2 | c.2790C>T p.G930= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as rs756950589; called by muse, mutect2, varscan2
- TMC1 | c.1365C>T p.Y455= | Silent (SNP) | VAF 204/426 reads (48%) | catalogued as rs750724544, COSV52774765; called by muse, mutect2, varscan2
- UBC | c.2049G>C p.G683= | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as COSV100299058; called by muse, mutect2
- VSIG10 | c.1182A>C p.V394= | Silent (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- ARHGAP31 | c.*48A>C | 3'UTR (SNP) | VAF 19/325 reads (6%) | called by muse, mutect2
- PLEKHH1 | c.3933+349T>A | Intron (SNP) | VAF 82/281 reads (29%) | called by muse, mutect2, varscan2
- SLC10A3 | c.-78C>A | 5'UTR (SNP) | VAF 79/182 reads (43%) | called by muse, mutect2, varscan2
- SP110 | c.1590+839G>T | Intron (SNP) | VAF 39/523 reads (7%) | catalogued as COSV51250184; called by muse, mutect2
